Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6520, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6520-01A (Primary Tumor).

[page 1 of 2]
Examination: **Histopathological examination**

Material: 1. Total organ resection – stomach

TCGA – D7 – 6520

Physician in charge:

Material collected on Material received on

Expected time of examination

Clinical diagnosis: **Cancer of the gastric body.**

Examination performed on:

Macroscopic description:

Sent material consisting of the stomach, after being cut out along the greater curvature, sized 16 x 18 cm with the omentum sized 24 x 18 cm.

Edge-thickened ulceration in the pyloric region sized of 7 x 6 x 1.7 cm.

The invasion macroscopically infiltrates the muscular membrane.

Distance from the proximal end 7.5 cm, from distal end 1.5 cm.

[page 2 of 2]
Microscopic description:

Adenocarcinoma male differentiatum partim tubulare G3.

The tumour invades through the full thickness of the stomach wall, vessels, perigastric fat tissue, and reaches the surface of the peritoneum.

Incision lines free of neoplastic invasion.

Mucous membrane off tumour showing features of chronic inflammation.

Lymph nodes:

1,2 - (periostic): Lymphonodulitis reactiva (No VI).

3 - (lesser curvature): metastases carcinomatosae in lymphonodis (No V/IX).

Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

4 - (greater curvature): metastases carcinomatosae in lymphonodis (No VIII/X).

Infiltratio carcinomatosa capsulae lymphonodorum.

6 - (peripyloric): metastases carcinomatosae in lymphonodis (No I/I).

Histopathological diagnosis:

Adenocarcinoma male differentiatum partim tubulare ventriculi. Poorly differentiated and partially tubular adenocarcinoma of the stomach

Metastases carcinomatosae in lymphonodis (No XIV/XXIV). Cancer metastases in the lymph nodes (No XIV/XXIV)

Invasio carcinomatosa vasorum. Cancerous invasion of the vessels.

G3, pT2b, pN2 ty pus intestinalis sec. [REDACTED]

Examination: Histopathological examination (cito) page 2 / 2

Results of immunohistochemical examination:

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 0)

Source: NCI Genomic Data Commons file 7fec3601-2a87-4a38-a795-7a2ae42ed567 (TCGA-D7-6520.9D50E818-91ED-45DB-A51D-F70A944017AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).